Gene-level copy-number profile of specimen HCM-SANG-0545-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0545-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0545-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file cb06240d-7324-40e3-b667-2a68f983ee29.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0545-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,228 have no estimate.
https://portal.gdc.cancer.gov/files/45033252-237e-47ee-9164-3d77e49480dd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,268; copy number 2: 16,923; copy number 3: 27,848; copy number 4: 8,898; copy number 5: 2,651; copy number 6: 104; copy number 7: 34; copy number 8: 16; copy number 9: 77; copy number 10: 15; copy number 11: 59; copy number 12: 7; copy number 13: 7; copy number 14: 1; copy number 15: 55; copy number 16: 18; copy number 17: 3; copy number 18: 120; copy number 19: 143; copy number 20: 9; copy number 26: 1; copy number 31: 14; copy number 32: 8; copy number 33: 10; copy number 34: 4; copy number 36: 3; copy number 37: 5; copy number 39: 28; copy number 41: 32; copy number 42: 8; copy number 44: 1; copy number 50: 6; copy number 54: 16; copy number 58: 3.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 703 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:175,877,343–176,447,919, 13 genes, copy number 8: LINC01657, LINC02803, RPS29P5, COP1, SCARNA3, AL590723.1, AL591043.2, U7, AL359265.2, RNU2-12P, AL359265.1, AL591043.1, MORF4L1P7.
- chr3:8,980,591–14,352,568, 130 genes, copy number 10–20 (broad region; genes not listed).
- chr3:15,151,833–15,601,852, 15 genes, copy number 8–11: COL6A4P1, CAPN7, SH3BP5-AS1, SH3BP5, RNU6-454P, HMGN2P7, METTL6, EAF1, RNU6-1024P, EAF1-AS1, COLQ, MIR4270, AC027129.1, RN7SL110P, HACL1.
- chr7:91,264,433–92,971,299, 32 genes, copy number 10–58: FZD1, AC079760.2, NIPA2P1, AC079760.1, AC000058.1, MTERF1, AKAP9, CYP51A1, AC000120.2, AC000120.3, CYP51A1-AS1, LRRD1, KRIT1, AC000120.1, Y_RNA, MIR1285-1, ANKIB1, TMBIM7P, AC007566.2, GATAD1, AC007566.1, ERVW-1, PEX1, RBM48, AC005156.1, FAM133B, CDK6, AC000065.2, AC000065.1, RNU6-10P, CDK6-AS1, RN7SL7P.
- chr10:34,109,560–35,231,394, 19 genes, copy number 9: PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P.
- chr10:36,432,882–37,992,467, 30 genes, copy number 9: MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA, AL390061.1, MKNK2P1, ARL6IP1P2, ANKRD30A, RNU6-811P, AL157387.1, LINC00993, RN7SL314P, Y_RNA, TMEM161BP1, VN1R53P, TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT.
- chr11:66,509,079–66,568,879, 7 genes, copy number 32 (within-gene range 2–32): AP002748.5, BBS1, AP002748.6, ZDHHC24, ACTN3, AP002748.2, CTSF.
- chr11:67,602,880–70,436,584, 97 genes, copy number 18 (broad region; genes not listed).
- chr11:72,239,077–72,434,680, 9 genes, copy number 33 (within-gene range 2–33): PHOX2A, AP000593.2, AP000593.4, AP000593.1, CLPB, AP000593.3, AP002892.2, AP002892.1, AP003785.1.
- chr11:72,562,044–72,843,674, 17 genes, copy number 8–9 (within-gene range 2–9): AP005019.1, LINC01537, PDE2A, PDE2A-AS2, MIR139, RNU7-105P, PDE2A-AS1, ARAP1, ARAP1-AS1, AP003065.1, ARAP1-AS2, RPS12P20, STARD10, Y_RNA, MIR4692, AP002381.2, ATG16L2.
- chr11:76,591,023–82,718,299, 81 genes, copy number 19–41 (broad region; genes not listed).
- chr11:83,455,012–85,627,922, 1 gene, copy number 11 (within-gene range 3–19): DLG2.
- chr11:84,545,131–89,065,945, 78 genes, copy number 11–19 (broad region; genes not listed).
- chr12:21,437,615–23,251,499, 34 genes, copy number 7: PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1, CMAS, ST8SIA1, AC007671.1, SULT6B2P, RNU1-149P, AC087318.1, AC053513.1, C2CD5, AC053513.2, LRRC34P1, AC087241.1, AC087241.2, ETNK1, AC084816.1, RPS27P22, AC084819.1, AC087258.1, AC087235.2, AC087235.1.
- chr12:37,575,587–37,576,384, 1 gene, copy number 10: ZNF970P.
- chr12:41,188,320–41,574,745, 2 genes, copy number 9–10: PDZRN4, AC090531.1.
- chr12:54,353,661–54,497,688, 1 gene, copy number 9 (within-gene range 3–10): AC079313.2.
- chr12:54,428,303–54,687,434, 10 genes, copy number 9 (within-gene range 3–10): LINC01154, GTSF1, NCKAP1L, AC068789.1, PDE1B, PPP1R1A, GLYCAM1, LACRT, DCD, AC079310.1.
- chr12:65,017,468–66,276,651, 32 genes, copy number 36–44: AC135895.1, WIF1, RNU6-166P, APOOP3, LEMD3, AC026124.2, MSRB3, AC026124.1, KRT18P60, AC025419.1, AC090023.1, LINC02454, AC090023.2, PCNPP3, RPSAP52, HMGA2, AC107308.1, HMGA2-AS1, AC090673.1, MIR6074, LINC02425, RPL21P18, RNA5SP362, LLPH, AC078927.1, LLPH-DT, TMBIM4, IRAK3, RBMS1P1, MIR6502, AC078889.1, PDCL3P7.
- chr12:68,332,888–70,543,040, 56 genes, copy number 26–42 (within-gene range 3–42): LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1.
- chr12:71,007,773–71,586,310, 6 genes, copy number 10–11 (within-gene range 3–11): AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1.
- chr12:72,727,923–75,511,636, 32 genes, copy number 10–34 (within-gene range 10–35): AC133480.1, AC090503.2, LINC02444, AC090503.1, AC087879.1, RNU6-1012P, LINC02445, U8, LINC02882, AC136188.1, LINC02394, AC090502.3, AC090502.2, AC090502.1, VENTXP3, ATXN7L3B, AC025257.1, AC123904.2, AC123904.1, AC123904.3, AC073525.1, KCNC2, CAPS2-AS1, CCNG2P1, CAPS2, AC092552.1, AC121761.2, GLIPR1L1, GLIPR1L2, GLIPR1, AC121761.1, KRR1.

Autosomal genes at a single copy (total copy number 1): 1,268. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
